Somatic mutation profile of tumor specimen MBCProject_4423_T1_WES (aliquot MBCProject_4423_T1_WES_1) from CMI case MBCProject_4423, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 44.0 years (16,073 days).
Specimen MBCProject_4423_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 747bdd86-ef93-47ca-af61-ecbd577d00cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4423_SALIVA (Saliva), aliquot MBCProject_4423_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28e29781-c500-45c1-9544-954d15d987d8

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 1, 5'Flank 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OPN1LW | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 158/483 reads (33%) | catalogued as rs104894912, CM931121; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COQ8B | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 109/295 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs746915084, COSV53287650; called by muse, mutect2, varscan2
- DMD | c.7244G>A p.R2415H | Missense Mutation (SNP) | VAF 31/519 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373749120, COSV58899961; ClinVar: likely benign / benign; called by muse, mutect2
- KIFC3 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs146824728; called by muse, mutect2, varscan2
- MUC12 | c.6521C>T p.T2174M (on ENST00000379442; = p.T2031M on NM_001164462.1) | Missense Mutation (SNP) | VAF 302/2378 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs762311937; called by muse, varscan2
- ZDHHC1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776487512; called by muse, mutect2, varscan2
- GABRB2 | c.1258G>T p.A420S (on ENST00000274547; = p.A382S on NM_000813.3) | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.042); called by muse, mutect2
- MUC22 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.2); called by muse, mutect2
- NFIC | c.1171del p.H391Tfs*34 (on ENST00000443272 / NM_001245002.2; = p.H391Tfs*72 on NM_005597.4) | Frame Shift Del (DEL) | VAF 87/271 reads (32%) | called by mutect2, pindel, varscan2
- OPN3 | c.746A>T p.Y249F | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- PGLYRP3 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 106/483 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- RSC1A1 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- STAG2 | c.1143C>A p.D381E | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- UNCX | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- AQP4 | c.336C>A p.I112= | Silent (SNP) | VAF 163/463 reads (35%) | catalogued as rs771087375, COSV67219285; called by muse, mutect2, varscan2
- LINGO1 | c.630G>A p.A210= | Silent (SNP) | VAF 84/223 reads (38%) | catalogued as rs553512567; called by muse, mutect2, varscan2
- RHBDL1 | c.591C>T p.P197= (on ENST00000219551 / NM_001318733.2; = p.P132= on NM_001278720.2) | Silent (SNP) | VAF 63/155 reads (41%) | catalogued as rs765266063, COSV53484379; called by muse, mutect2, varscan2
- AC092865.4 | chr12:8390653 G>T | 5'Flank (SNP) | VAF 8/44 reads (18%) | catalogued as rs190105354; called by muse, mutect2
- AK9 | c.3633+13del | Intron (DEL) | VAF 9/38 reads (24%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
